Somatic mutation profile of tumor specimen 0DHBD8 from CCDI case PBBUKY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 10.0 years (3,667 days).
Specimen 0DHBD8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d3c21f8-6ca6-4601-b5aa-77344e2fde26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHBCU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3379d50-e6fe-4a3d-b33c-d7c159d72fa1

The open-access MAF lists 26 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 6, Nonsense Mutation 3, 5'UTR 2, Silent 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCF1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 20/531 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs767397757, COSV58228252; called by muse, mutect2
- COL22A1 | c.1054C>T p.R352* | Nonsense Mutation (SNP) | VAF 421/1037 reads (41%) | catalogued as rs749819644, COSV57323940; called by muse, mutect2, varscan2
- KMT2C | c.3596G>A p.R1199Q | Missense Mutation (SNP) | VAF 167/1256 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as rs4024346, COSV51422598; called by muse, mutect2, varscan2
- NARF | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 105/333 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as rs760317433; called by muse, mutect2, varscan2
- PML | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 290/694 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761685300, COSV51450320; called by muse, varscan2
- AGRN | c.3235G>T p.G1079W | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 58/1712 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CCDC168 | c.4588C>T p.Q1530* | Nonsense Mutation (SNP) | VAF 32/1048 reads (3%) | called by muse, mutect2
- CD69 | c.527T>A p.L176Q | Missense Mutation (SNP) | VAF 65/1387 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- H2AC17 | c.363_365del p.E122del | In Frame Del (DEL) | VAF 242/575 reads (42%) | called by mutect2, varscan2
- IRF6 | c.787G>C p.E263Q | Missense Mutation (SNP) | VAF 250/543 reads (46%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- MAML2 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 26/206 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUSK | c.1722C>G p.N574K | Missense Mutation (SNP) | VAF 156/2194 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRPF8 | c.3793A>G p.T1265A | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.859); called by muse, mutect2
- TUBGCP2 | c.1871G>A p.W624* | Nonsense Mutation (SNP) | VAF 14/421 reads (3%) | called by muse, mutect2
- C12orf50 | c.1008C>T p.H336= | Silent (SNP) | VAF 243/1200 reads (20%) | catalogued as rs772176508, COSV100072272; called by muse, mutect2, varscan2
- CDC25B | c.1641C>T p.H547= (on ENST00000245960 / NM_021873.3; = p.H533= on NM_004358.4) | Silent (SNP) | VAF 208/500 reads (42%) | catalogued as rs764885329, COSV99848293; called by muse, mutect2, varscan2
- ACADM | c.1194+45T>G | Intron (SNP) | VAF 165/401 reads (41%) | called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 64/624 reads (10%) | called by muse, varscan2
- FOXK1 | c.-9C>T | 5'UTR (SNP) | VAF 67/113 reads (59%) | called by muse, mutect2, varscan2
- GCFC2 | c.1145-91T>A | Intron (SNP) | VAF 13/129 reads (10%) | called by muse, varscan2
- GCFC2 | c.1145-92T>A | Intron (SNP) | VAF 12/124 reads (10%) | called by muse, varscan2
- MARF1 | c.3077+17C>T | Intron (SNP) | VAF 86/208 reads (41%) | called by muse, mutect2, varscan2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 39/364 reads (11%) | called by muse, varscan2
- SAFB | c.2335-68T>C | Intron (SNP) | VAF 14/39 reads (36%) | called by muse, mutect2
- TCF4 | c.73-62T>C | Intron (SNP) | VAF 218/543 reads (40%) | called by muse, mutect2, varscan2
